Somatic mutation profile of tumor specimen ALCH-B6YR-TTP1-A (aliquot ALCH-B6YR-TTP1-A-6-0-D-A95P-47) from ALCHEMIST case ALCH-B6YR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.0 years (20,082 days).
Specimen ALCH-B6YR-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54b03656-caf6-4483-8f49-e8e9f407a820.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B6YR-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B6YR-NB1-A-1-0-D-A95P-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21e25178-0ead-4491-aee1-7ddeae3b67ec

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, Intron 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN3A1 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV50025319; called by muse, mutect2, varscan2
- PPP3CC | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs1332872876; called by muse, mutect2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 18/142 reads (13%) | catalogued as rs756557178; called by mutect2, varscan2
- SEMA3E | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1049236480, COSV100317149; called by muse, mutect2
- SLC35F5 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs375944618; called by mutect2, varscan2
- ARHGEF2 | c.1650G>C p.E550D (on ENST00000361247 / NM_001162383.2; = p.E522D on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC40 | c.2236G>A p.G746R | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PRPF3 | c.1976A>C p.E659A | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAB26 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- TMEM87B | c.237_238insTAAACAGTTAAGTTC p.F79_H80ins* | Nonsense Mutation (INS) | VAF 14/145 reads (10%) | called by mutect2, pindel*
- UBE2L5 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2
- ZNF626 | c.1424A>G p.H475R | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BCAS3 | c.2571C>T p.G857= (on ENST00000390652 / NM_001353144.2; = p.G842= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
- CPT1C | c.1407G>A p.E469= | Silent (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2514G>A p.L838= | Silent (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- EEF1AKMT3 | c.582C>T p.H194= | Silent (SNP) | VAF 74/308 reads (24%) | catalogued as rs560895416; called by muse, mutect2, varscan2
- GPX7 | c.165C>T p.S55= | Silent (SNP) | VAF 35/257 reads (14%) | catalogued as rs764261634, COSV63652555; called by muse, mutect2, varscan2
- OR2L13 | c.474C>T p.H158= | Silent (SNP) | VAF 32/308 reads (10%) | called by mutect2, varscan2
- OTOGL | c.6243C>T p.N2081= (on ENST00000547103; = p.N2072= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- ZFHX3 | c.528C>T p.G176= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs760303298; called by muse, mutect2, varscan2
- MYOZ3 | c.216+32A>C | Intron (SNP) | VAF 60/313 reads (19%) | called by muse, mutect2, varscan2
- PXN | c.832-898C>A | Intron (SNP) | VAF 26/150 reads (17%) | called by muse, varscan2
- SON | c.6657+107G>T | Intron (SNP) | VAF 12/162 reads (7%) | catalogued as rs1317722187; called by muse, mutect2
